Surgical pathology report (de-identified scan), TCGA case TCGA-95-7944, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Emory, specimen TCGA-95-7944-01A (Primary Tumor).

[page 1 of 5]
Anat Path Reports

* Final Report *

Document Type: Anat Path Reports
Document Date: [REDACTED]
Document Status: Auth (Verified)
Document Title: Histology
Encounter info: [REDACTED]

* Final Report *

APRPT (Verified)

Patient Name: [REDACTED] Acc #: [REDACTED]
MRN: [REDACTED] DOB: [REDACTED]
Location: [REDACTED] Gender: M
Client: [REDACTED] Collected: [REDACTED]
Submitting Phys: [REDACTED] Received: [REDACTED]
Reported: [REDACTED]

Final Surgical Pathology Report

Final Pathologic Diagnosis

- A. LUNG, LEFT LOWER LOBE, WEDGE RESECTION, A1FS:
- NON-SMALL CELL CARCINOMA (1.4 X 1.2 X 1.1 CM), FAVOR POORLY DIFFERENTIATED ADENOCARCINOMA
- NO LYMPHOVASCULAR INVASION IDENTIFIED.
- MARGINS OF RESECTIONS ARE NEGATIVE.
- SEE SYNOPSIS REPORT AND COMMENT.
- B. LYMPH NODE, #9, EXCISION, B1FS-B2FS:
- TWO LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/2).
- C. LYMPH NODE, #7, EXCISION, C1FS:
- ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).
- D. LYMPH NODE, #6, EXCISION, D1FS-D2FS:
- THREE LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/3).
- E. LYMPH NODE, #10L, EXCISION, E1FS:

Printed by: [REDACTED]
Printed on: [REDACTED]

[page 2 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of [REDACTED] regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

- TWO LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/2).

F. LUNG, LEFT LOWER LOBE, EXTENDED WEDGE RESECTION:
- LUNG PARENCHYMA NEGATIVE FOR CARCINOMA.

Comment

Immunohistochemical stains for TTF-1, p63 and Ck5 are negative

Synoptic Worksheet

B. #9 lymph node:

Specimen:	Lobe(s) of lung: left lower lobe
Procedure:	Wedge resection
Specimen Integrity:	Intact
Specimen Laterality:	Left
Tumor Site:	Lower lobe
Tumor Focality:	Unifocal
Histologic Type:	Adenocarcinoma
Histologic Grade:	G3: Poorly differentiated
Tumor Size:	Greatest dimension: 1.4 cm Additional dimension: 1.2 cm Additional dimension: 1.1 cm
Visceral Pleura Invasion:	Not identified
Tumor Extension:	Not identified
Bronchial Margin:	Involvement by invasive carcinoma not applicable Involvement by squamous cell carcinoma in situ (CIS) not applicable
Vascular Margin:	Not applicable
Parenchymal Margin:	Uninvolved by invasive carcinoma
Parietal Pleural Margin:	Not applicable
Chest Wall Margin:	Not applicable
Other Attached Tissue Margin:	Not applicable
All Margins Uninvolved By Invasive Carcinoma:	Distance of invasive carcinoma from closest margin: 39 mm Margin closest to invasive carcinoma:: parenchymal
Treatment Effect:	Not applicable
Lymph-Vascular Invasion:	Not identified
TNM Descriptors:	Not applicable
Primary Tumor (pT):	pT1a: Tumor 2 cm or less in greatest dimension, surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal

[page 3 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of [REDACTED] regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

Regional Lymph Nodes (pN):	than the lobar bronchus (ie, not in the main bronchus); or Superficial spreading tumor of any size with its invasive component limited to the bronchial wall, which may extend proximally to the main bronchus pN0: No regional lymph node metastasis Nodes examined: 0 Nodes involved: 8
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	None identified

Clinical History

Left video-assisted thorascopic surgery, wedge resection.

Specimen(s) Received

A: Left lower lobe wedge, FS
B: #9 lymph node
C: Lymph node #7
D: Lymph node #6
E: Lymph node #10L
F: Extended wedge, left lower lobe

Gross Description

Six specimens are received fresh for intraoperative consultation, each labeled with the patient's name and medical record number.

Specimen A is further labeled "left lower lobe wedge." It consists of a wedge of lung measuring 6.8 x 2.5 x 2.1 cm and weighing 12.7 grams. The pleural surface has been previously opened to reveal a 1.4 x 1.2 x 1.1 cm firm yellow mass that is 0.3 cm from the stapled surgical resection margin. The remaining lung parenchyma is unremarkable. A representative section of the mass and of normal lung is submitted for Tumor Bank. The specimen is inked as follows: pleural surface blue, surgical resection margin underneath staple line green. A portion of the mass is submitted for intraoperative consultation and transferred to cassette "A1FS." The remaining cassette summary is as follows. [REDACTED]

Specimen B is labeled as "#9 lymph node" and consists of three lymph nodes that measure 1.2 to 2.2 cm in greatest dimension. Two lymph nodes are submitted for intraoperative consultation and transferred to cassette "B1FS." One lymph node is submitted for intraoperative consultation and transferred to cassette "B2FS." [REDACTED]

Specimen C is labeled as "lymph node #7" and consists of a fragment of tissue that measures 2.2 x 1.3 x 0.5 cm. One lymph node is identified. The lymph node is submitted for intraoperative consultation and transferred to cassette "C1FS." Additional tissue is submitted in cassette "C2." [REDACTED]

Specimen D is received fresh for intraoperative consultation and is labeled "lymph nodes #6." It consists of three lymph nodes ranging in size from 0.4 to 1.3 cm. The lymph nodes are submitted entirely for frozen section diagnosis in cassettes "D1FS" and "D2FS." [REDACTED]

Specimen E is received fresh for intraoperative consultation and is labeled "lymph nodes #10L." It consists of two lymph nodes

Printed by:
Printed on:

Page 3 of 5
(Continued)

[page 4 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures of [REDACTED] regarding patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

ranging in size from 1.0 cm to 1.1 cm. The lymph nodes are submitted entirely for frozen section diagnosis in cassette "E1FS."

Specimen F is received in formalin and labeled "extended wedge, left lower lobe." It consists of a portion of lung measuring 4.0 x 3.9 x 1.9 cm and weighing 13.0 grams. A ring of stapled margin entirely encircles the specimen. The lung parenchyma is unremarkable with no lesions identified. The specimen is inked as follows: resection margin green, pleura blue. Representative sections are submitted in cassettes "F1" through "F4."

Cassette Summary:

A2: Additional mass
A3: Surgical resection margin closest to mass
A4: Uninvolved lung
D1FS: Two lymph nodes, one bisected and one inked blue
D2FS: Lymph node, bisected

Intraoperative Consult Diagnosis

A1FS: LEFT LOWER LOBE WEDGE (FROZEN SECTION): POORLY DIFFERENTIATED CARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back by [REDACTED]

[REDACTED] and start time [REDACTED]

B1FS,B2FS: #9 LYMPH NODE (FROZEN SECTION): NEGATIVE FOR CARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back by [REDACTED]

In at [REDACTED]

C1FS: LYMPH NODE #7 (FROZEN SECTION): NEGATIVE FOR CARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back by [REDACTED]

in

at [REDACTED]

D1FS: LYMPH NODE #6 (FROZEN SECTION): NEGATIVE FOR CARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back by [REDACTED]

in

at [REDACTED]

E1FS: LYMPH NODE #10L (FROZEN SECTION): NEGATIVE FOR CARCINOMA.

Frozen section results were communicated to the surgical team and were repeated back by [REDACTED]

in

at [REDACTED]

Pathologist [REDACTED]

Microscopic Description

Microscopic examination performed.

Printed by:
Printed on:

Page 4 of 5
(Continued)

[page 5 of 5]
Anat Path Reports

* Final Report *

Source: NCI Genomic Data Commons file 0836e492-84ff-479d-adf8-3c4606707605 (TCGA-95-7944.567E989F-6896-4FAF-84BB-8EF786461228.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).